Gene-level copy-number profile of tumor specimen TCGA-23-2649-01A from TCGA case TCGA-23-2649, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.8 years (22,210 days).
Specimen TCGA-23-2649-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.9b345bb6-89dc-403a-b97b-3d4565942415.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-2649-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate.
https://portal.gdc.cancer.gov/files/5c350dd2-a201-447a-b387-c929b88a0475

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 3,758; copy number 2: 21,966; copy number 3: 21,943; copy number 4: 8,867; copy number 5: 1,782; copy number 6: 999; copy number 7: 233; copy number 8: 248; copy number 9: 6; copy number 12: 3.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.
- chr9:74,722,495–75,088,217, 11 genes: TRPM6, RN7SKP47, RPSAP75, RNU6-445P, AL158825.1, C9orf40, CARNMT1-AS1, CARNMT1, AL158825.2, AL158825.3, NMRK1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,196 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:161,258,745–175,335,459, 315 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:38,814–2,331,664, 40 genes, copy number 6 (within-gene range 4–6): FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN, MYT1L, AC093390.2, AC093390.1.
- chr2:60,640,705–61,888,671, 43 genes, copy number 5: RN7SL361P, IFITM3P9, RPL26P13, RNU6-612P, ATP1B3P1, PAPOLG, LINC01185, RN7SL632P, RPL21P33, REL, RNU4-51P, AC010733.1, NONOP2, RPS12P3, PUS10, RNA5SP95, PEX13, KIAA1841, AC016747.4, AC016747.1, C2orf74, AC016747.2, AHSA2P, USP34, AC016747.3, AC018889.1, AC016894.1, SNORA70B, AC016727.1, XPO1, AC016727.3, AC016727.2, RPS29P10, RNU6-1145P, AC108039.1, RPS24P7, AC108039.2, FAM161A, RPL31P30, AC107081.2, CCT4, AC107081.1, AC107081.3.
- chr2:61,928,634–61,928,704, 1 gene, copy number 5: Y_RNA.
- chr2:211,104,934–227,387,949, 272 genes, copy number 5 (broad region; genes not listed).
- chr3:177,019,340–177,228,000, 1 gene, copy number 7 (within-gene range 4–7): TBL1XR1.
- chr3:177,120,691–198,222,513, 474 genes, copy number 5–7 (broad region; genes not listed).
- chr4:41,883,060–42,152,878, 8 genes, copy number 5 (within-gene range 2–5): AC108210.1, AC108210.2, TMEM33, DCAF4L1, AC106052.1, SLC30A9, ATP1B1P1, BEND4.
- chr5:58,198–20,616,441, 358 genes, copy number 5–6 (broad region; genes not listed).
- chr7:22,419,444–29,514,667, 163 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr7:38,383,704–40,134,622, 32 genes, copy number 5 (within-gene range 3–5): AMPH, RN7SL83P, KRT8P20, FAM183BP, VPS41, POU6F2, POU6F2-AS2, SNORA20B, POU6F2-AS1, AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, AC004837.4, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P, AC072061.1, CDK13, AC006023.2, AC006023.1, MPLKIP, Y_RNA.
- chr7:40,151,613–40,154,151, 1 gene, copy number 5: THUMPD3P1.
- chr7:156,640,281–159,233,377, 44 genes, copy number 5: RNF32, RNF32-AS1, LMBR1, RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1, AC006967.2, AC006967.1, AC006967.3, UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2, DNAJB6, AC006372.3, AC006372.1, AC006372.2, AC006372.4, PTPRN2, MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:107,160,354–145,066,685, 569 genes, copy number 6–12 (broad region; genes not listed).
- chr9:31,165,618–31,645,160, 6 genes, copy number 9: AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23.
- chr9:33,247,820–35,875,194, 146 genes, copy number 6 (broad region; genes not listed).
- chr10:44,712–18,043,292, 314 genes, copy number 5–6 (broad region; genes not listed).
- chr10:18,206,127–18,261,504, 1 gene, copy number 5: AL390783.1.
- chr10:34,663,859–36,944,738, 38 genes, copy number 5: RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, LINC02635, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1.
- chr10:126,012,381–126,388,455, 1 gene, copy number 6 (within-gene range 4–6): ADAM12.
- chr10:126,272,818–133,761,125, 129 genes, copy number 6 (broad region; genes not listed).
- chr11:90,118,391–90,226,538, 6 genes, copy number 6: AP000648.1, AP000648.3, NAALAD2, AP000648.4, CHORDC1, AP002364.1.
- chr11:90,282,560–90,284,172, 1 gene, copy number 6: TUBAP2.
- chr20:34,516,414–35,092,807, 17 genes, copy number 5: DYNLRB1, Y_RNA, MAP1LC3A, PIGU, AL118520.1, NCOA6, TP53INP2, AL109824.1, HMGB3P1, GGT7, ACSS2, GSS, MYH7B, MIR499A, MIR499B, TRPC4AP, RNU6-407P.
- chr20:35,117,136–35,117,207, 1 gene, copy number 5: AL135844.1.
- chr21:23,281,736–33,588,706, 214 genes, copy number 5–6 (broad region; genes not listed).
- chr21:33,589,341–33,643,926, 1 gene, copy number 6: CRYZL1.

Autosomal genes at a single copy (total copy number 1): 3,758. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
